TCGA case TCGA-ZF-A9RG — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Sheffield. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1eb0adbf-dbe8-4736-97f6-2dc4ee30e943

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 70 years; Vital status: Alive.

Diagnoses (5)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 70.2 years (25,656 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,786 days (4.9 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 15; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lymph nodes of head, face and neck. Age at diagnosis: 71.4 years (26,096 days); Days to diagnosis: 440 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lymph nodes of head, face and neck. Age at diagnosis: 71.5 years (26,108 days); Days to diagnosis: 452 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 71.5 years (26,125 days); Days to diagnosis: 469 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS, for recurrent disease.
5. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 73.2 years (26,742 days); Days to diagnosis: 1,086 days (3.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (7 entries)
- Day 440 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to progression: 440 days (1.2 years).
- Day 452 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to progression: 452 days (1.2 years).
- Day 469 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 469 days (1.3 years).
- Day 1,086 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,086 days (3.0 years).
- Days to follow up: 1,600 days (4.4 years); Disease response: With Tumor.
- Days to follow up: 1,786 days (4.9 years); Disease response: With Tumor.
- ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 176 cm; BMI: 24.5.

Exposures
- Chemical exposure type: Chemical Exposure, NOS; Occupation duration years: 20; Occupation type: Architects, Planners, Surveyors and Designers.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZF-A9RG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-ZF-A9RG-01A-02-TSB: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZF-A9RG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZF-A9RG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: retired; Occupation primary: plan drawer in drawing office; Occupation primary chemical exposure: printing ink; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,786 days; disease-specific survival: no event (censored), 1,786 days; disease-free interval: event (new tumor event after initially disease-free), 440 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 440 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZF-A9RG-01A-21D-A42D-01): tumor purity 0.24, ploidy 3.15, whole-genome doublings 1.
